CCDI case PBCJKF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/a3552fdf-2135-4587-a1cf-b9d58eeb8b39

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.4 years (865 days).

Biospecimens (3 samples)
- Samples 0DTB8A, 0DTB8W (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTB8N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
